Gene-level copy-number profile of tumor specimen ALCH-AE5D-TTP1-A from ALCHEMIST case ALCH-AE5D, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.1 years (22,665 days).
Specimen ALCH-AE5D-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ce263de1-2677-4f1b-87fe-0b97aa38a0e8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE5D-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/02316e8d-0b59-4880-b2ef-7f7fbe579454

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 1,068; copy number 2: 52,337; copy number 3: 3,661; copy number 4: 1,204; copy number 5: 63; copy number 6: 10; copy number 7: 17; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,266,494–89,320,146, 7 genes: IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39.
- chr8:7,238,286–7,247,571, 2 genes: AF228730.3, OR7E125P.
- chr9:64,621,560–64,652,556, 2 genes: AQP7P2, AL445665.1.
- chr21:12,999,676–13,067,033, 3 genes: AP001464.1, ANKRD30BP2, RNU6-614P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 56 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:24,566,964–26,833,194, 50 genes, copy number 5–7: LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2.
- chr16:10,718,633–10,721,464, 3 genes, copy number 6: MTCYBP33, MTND6P33, MTND5P33.
- chr21:43,446,601–43,479,534, 3 genes, copy number 6–10 (within-gene range 6–20): LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 1,005. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
